Somatic mutation profile of tumor specimen TCGA-22-1002-01A (aliquot TCGA-22-1002-01A-01D-1521-08) from TCGA case TCGA-22-1002, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.4 years (25,359 days).
Specimen TCGA-22-1002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48cc8682-106f-45d2-9167-51db353e0edd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1002-11A (Solid Tissue Normal), aliquot TCGA-22-1002-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53a6121b-ca91-4853-9afc-7776828261bd

The open-access MAF lists 233 somatic variants for this specimen: 182 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 45, Nonsense Mutation 15, Frame Shift Del 5, RNA 3, Intron 2, Splice Site 2, Frame Shift Ins 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF6 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 33/127 reads (26%) | catalogued as rs1057520569, CM022392, COSV65419443; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15536G>T p.R5179L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as CM105472, COSV56428259, COSV56447076, COSV56496109; called by muse, mutect2, varscan2
- A2ML1 | c.3920G>T p.C1307F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749887494, COSV55291616; called by muse, mutect2, varscan2
- ABCC5 | c.1893G>C p.Q631H | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV55591004; called by muse, mutect2, varscan2
- ADAT2 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52794582; called by muse, mutect2, varscan2
- ADCY3 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 67/401 reads (17%) | catalogued as COSV53168114; called by muse, mutect2, varscan2
- ADGRL4 | c.1118G>A p.W373* | Nonsense Mutation (SNP) | VAF 23/137 reads (17%) | catalogued as COSV66061987; called by muse, mutect2, varscan2
- ANK2 | c.3539A>C p.Q1180P | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52164138; called by muse, mutect2, varscan2
- AP3B2 | c.660C>A p.N220K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1280464630, COSV55610117; called by muse, mutect2, varscan2
- APBA2 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV101382517, COSV68791854; called by muse, mutect2
- APLNR | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57242856, COSV99951412; called by muse, mutect2
- APOA4 | c.326T>A p.L109Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV63360505; called by muse, mutect2
- ARHGAP33 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs937210289, COSV50125166; called by muse, mutect2, varscan2
- ARHGAP33 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV50125197; called by muse, mutect2, varscan2
- ARHGAP35 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 56/391 reads (14%) | catalogued as COSV68328962; called by muse, mutect2, varscan2
- ARHGEF9 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53639059; called by muse, mutect2, varscan2
- ARPP21 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51799170; called by muse, mutect2, varscan2
- ATG7 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV61612906; called by muse, mutect2, varscan2
- B3GALNT2 | c.1191G>C p.W397C | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64004032; called by muse, mutect2
- BICC1 | c.2480A>G p.H827R | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as rs1252958163, COSV54064126; called by muse, mutect2, varscan2
- BNC2 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1265616963, COSV66148617; called by muse, mutect2, varscan2
- BRINP3 | c.654T>A p.S218R | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66526216; called by muse, mutect2, varscan2
- CA11 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.905); catalogued as COSV50033159; called by muse, mutect2, varscan2
- CAPZA3 | c.740T>A p.L247* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | catalogued as COSV56853352; called by muse, mutect2, varscan2
- CASQ2 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV54769365, COSV54770961; called by muse, mutect2, varscan2
- CD80 | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 85/482 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV51802460; called by muse, mutect2, varscan2
- CDYL | c.1544G>T p.C515F (on ENST00000328908 / NM_001368125.1; = p.C461F on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV59359944; called by muse, mutect2, varscan2
- CERK | c.1053C>A p.C351* | Nonsense Mutation (SNP) | VAF 34/151 reads (23%) | catalogued as COSV53451627; called by muse, mutect2, varscan2
- CERS5 | c.1152G>T p.M384I | Missense Mutation (SNP) | VAF 65/383 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV100451924; called by muse, mutect2, varscan2
- CFAP91 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 156/616 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV56341421, COSV99847287; called by muse, mutect2, varscan2
- CIC | c.2698G>C p.A900P | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as COSV50581616; called by muse, mutect2
- CLK1 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58433140, COSV58433991; called by muse, mutect2, varscan2
- CLVS2 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV51563593; called by muse, mutect2, varscan2
- CRB1 | c.1773C>A p.C591* | Nonsense Mutation (SNP) | VAF 12/258 reads (5%) | catalogued as COSV66330865; called by muse, mutect2
- CSNK1D | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV53924852; called by muse, mutect2, varscan2
- CUBN | c.882A>G p.T294= | Splice Region (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100912239; called by muse, mutect2, varscan2
- DCAF5 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 70/410 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV58460720; called by muse, mutect2, varscan2
- DCT | c.1043+1G>A p.X348_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100986135; called by mutect2, varscan2
- DGKI | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV55952987; called by muse, mutect2, varscan2
- DMRT1 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66521741; called by muse, mutect2, varscan2
- DNAH11 | c.10202A>G p.E3401G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV60958710; called by muse, mutect2, varscan2
- DOCK6 | c.5107G>T p.V1703L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53915757; called by muse, mutect2, varscan2
- DRC1 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV56531985; called by muse, mutect2, varscan2
- DSCAM | c.3211G>T p.G1071C | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101259448; called by muse, mutect2, varscan2
- DZIP3 | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 31/339 reads (9%) | catalogued as COSV64312286; called by muse, mutect2
- EHMT1 | c.2749G>T p.G917C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71778080, COSV71778566; called by muse, mutect2, varscan2
- ENOX2 | c.618G>T p.Q206H (on ENST00000338144 / NM_001382520.1; = p.Q177H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV57652407; called by muse, mutect2, varscan2
- ENPEP | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754159304, COSV54451929; called by mutect2, varscan2
- EPB41L3 | c.1687A>T p.R563W | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as COSV59455548; called by muse, mutect2, varscan2
- ERBB4 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.084); catalogued as rs78887537, COSV53538135; called by muse, mutect2, varscan2
- EXOC2 | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV57865682; called by muse, mutect2, varscan2
- FBN1 | c.2935G>T p.A979S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.85); catalogued as rs748915171, COSV57318624; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN3 | c.695G>T p.C232F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54462493; called by muse, mutect2
- FBXO47 | c.606C>G p.C202W | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV65241896; called by muse, varscan2
- FER1L6 | c.2937C>A p.Y979* | Nonsense Mutation (SNP) | VAF 66/357 reads (18%) | catalogued as COSV67550366; called by muse, mutect2, varscan2
- FLNC | c.3529A>T p.T1177S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.06); catalogued as COSV57956856; called by muse, mutect2, varscan2
- GALNT17 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100351848, COSV61161682; called by muse, mutect2, varscan2
- GIGYF2 | c.2026A>T p.I676F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV65250145; called by muse, mutect2, varscan2
- GLI3 | c.2212A>G p.I738V | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1282627104, COSV67885107; called by muse, mutect2, varscan2
- GMNN | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV57777023; called by muse, mutect2, varscan2
- GNA12 | c.487A>T p.I163F | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51741410, COSV99282470; called by muse, mutect2, varscan2
- GOT1L1 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV56875924; called by muse, mutect2, varscan2
- GRIK3 | c.353C>A p.T118N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV66140613; called by muse, mutect2, varscan2
- GUSB | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100512540; called by muse, mutect2
- H2BC5 | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.712); catalogued as COSV56801402; called by muse, mutect2, varscan2
- HAS2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58264051, COSV58264390; called by muse, mutect2, varscan2
- HNRNPM | c.1369A>G p.M457V | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs760285171, COSV55314099; called by muse, mutect2, varscan2
- HTATIP2 | c.553A>G p.R185G | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV58177573; called by muse, mutect2, varscan2
- HTR1E | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 45/486 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59508419; called by muse, mutect2
- HYDIN | c.11261G>A p.W3754* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV66639341; called by muse, mutect2, varscan2
- IDH3B | c.122A>G p.E41G | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV66483374; called by muse, mutect2
- IL1RL1 | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.054); catalogued as COSV52116566; called by muse, mutect2, varscan2
- ILVBL | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779716944, COSV54620014; called by muse, mutect2, varscan2
- IQCN | c.1633G>T p.G545C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV66574659; called by muse, mutect2
- IQSEC2 | c.1837G>T p.G613C (on ENST00000642864 / NM_001111125.3; = p.G408C on NM_015075.2) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64725824; called by muse, mutect2, varscan2
- ITGAD | c.1660C>G p.L554V | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV66758307; called by muse, mutect2, varscan2
- ITGB1 | c.445A>G p.M149V | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV56482416, COSV56487476; called by muse, mutect2, varscan2
- JMY | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68661122; called by muse, mutect2, varscan2
- KCNC3 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs867151040, COSV65387698; called by muse, mutect2
- KCNH4 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs756662029, COSV52918193; called by muse, mutect2, varscan2
- KIF18B | c.1145C>A p.A382D | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV59273480; called by muse, mutect2, varscan2
- KIF20A | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50150488; called by muse, mutect2, varscan2
- KMT2D | c.4154G>T p.S1385I | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56447098, COSV99983357; called by muse, mutect2, varscan2
- KRTAP10-1 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59964813; called by muse, mutect2, varscan2
- KRTAP11-1 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60094619; called by muse, mutect2, varscan2
- LEPROT | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 118/692 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as rs770318763, COSV100756535, COSV60746319; called by muse, mutect2, varscan2
- LGI1 | c.144T>A p.C48* | Nonsense Mutation (SNP) | VAF 42/243 reads (17%) | catalogued as COSV65058136; called by muse, mutect2, varscan2
- LIG4 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63597170; called by muse, mutect2
- LNX2 | c.599G>T p.W200L | Missense Mutation (SNP) | VAF 78/462 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV60336028; called by muse, mutect2
- LRRC32 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as rs756642942, COSV52633290, COSV99476881; called by muse, mutect2, varscan2
- LRRC7 | c.3495G>T p.M1165I (on ENST00000651989 / NM_001370785.2; = p.M1132I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV50469937; called by muse, mutect2, varscan2
- LSM14A | c.1175A>G p.N392S | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70885156; called by muse, mutect2, varscan2
- MAGEL2 | c.2466G>T p.Q822H | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as COSV58567477; called by muse, mutect2, varscan2
- MAPK1 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53186825; called by muse, mutect2, varscan2
- MED18 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 137/484 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746391682, COSV65790374; called by muse, mutect2, varscan2
- MEGF10 | c.1427-2A>G p.X476_splice | Splice Site (SNP) | VAF 20/118 reads (17%) | catalogued as COSV57250085; called by muse, varscan2
- METTL7B | c.727G>T p.V243F | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57696045; called by muse, mutect2, varscan2
- MPHOSPH10 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV54906107; called by muse, mutect2, varscan2
- MUC16 | c.18718T>A p.L6240M | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV67470338; called by muse, mutect2, varscan2
- MUC16 | c.16502C>A p.T5501K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV67470346; called by muse, mutect2, varscan2
- MUC16 | c.16267G>A p.A5423T | Missense Mutation (SNP) | VAF 79/821 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs138208562; called by muse, mutect2
- MUC5B | c.15962G>A p.R5321K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs779334108, COSV71592361; called by muse, mutect2
- MYH3 | c.4864G>A p.D1622N | Missense Mutation (SNP) | VAF 131/633 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs753924310, COSV56865735; called by muse, mutect2, varscan2
- NECTIN4 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs750765099, COSV63512857; called by muse, mutect2, varscan2
- NEUROD6 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51771677; called by muse, varscan2
- NLK | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV69409061; called by muse, mutect2, varscan2
- NOS2 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs746500685, COSV58224300; called by muse, mutect2, varscan2
- NSD3 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 355/2723 reads (13%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.977); catalogued as COSV57670237; called by muse, mutect2, varscan2
- NYNRIN | c.5260G>T p.D1754Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs756219353, COSV66842897; called by muse, mutect2, varscan2
- OLFM3 | c.299T>A p.I100N (on ENST00000338858 / NM_001288821.1; = p.I80N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV58799361; called by muse, mutect2, varscan2
- OR10A7 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV100406519; called by muse, varscan2
- OR10V1 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55695747, COSV55698315; called by muse, mutect2, varscan2
- OR4C13 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101634149, COSV101634182; called by muse, mutect2, varscan2
- OR52B4 | c.662T>G p.M221R | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV68769023; called by muse, mutect2, varscan2
- OR52J3 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66747040; called by muse, mutect2
- OR6X1 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV60009875, COSV60010189; called by muse, mutect2, varscan2
- PAPPA | c.4838C>A p.A1613D | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs537619729, COSV60284619; called by muse, mutect2, varscan2
- PCDHA13 | c.1425C>G p.F475L | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV56507737; called by muse, varscan2
- PCDHA6 | c.2228G>A p.S743N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as COSV65344562; called by muse, mutect2, varscan2
- PCDHB7 | c.2266G>T p.G756C | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV50773683; called by muse, mutect2
- PDGFRA | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57268909, COSV57269165; called by muse, mutect2, varscan2
- PDILT | c.1093A>T p.S365C | Missense Mutation (SNP) | VAF 72/369 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56702248; called by muse, mutect2, varscan2
- PECR | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54734620; called by muse, mutect2, varscan2
- PGAP1 | c.2713C>A p.L905I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61326534; called by muse, mutect2, varscan2
- PGS1 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs374120789; called by muse, mutect2, varscan2
- PLCE1 | c.2809G>T p.D937Y | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53352922; called by muse, mutect2, varscan2
- POFUT2 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.278); catalogued as rs748785565, COSV57957513; called by muse, mutect2, varscan2
- POLDIP2 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 19/495 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV50228482; called by muse, mutect2
- PPP1R26 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV63355792; called by muse, mutect2, varscan2
- PREX1 | c.4917G>T p.Q1639H | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV64252445; called by muse, mutect2, varscan2
- PREX1 | c.3725G>T p.S1242I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV64252450; called by muse, mutect2
- PRKD1 | c.2167G>T p.V723L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.313); catalogued as COSV59571165; called by muse, mutect2
- PRUNE2 | c.8290G>T p.D2764Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56316690; called by muse, mutect2, varscan2
- PTPRB | c.4020del p.W1340* | Frame Shift Del (DEL) | VAF 59/460 reads (13%) | catalogued as COSV54250880; called by mutect2, pindel, varscan2
- PZP | c.2878A>G p.I960V | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV54361985; called by muse, varscan2
- RASEF | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV64587281; called by muse, mutect2, varscan2
- RASGEF1B | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV52337522; called by muse, mutect2
- RNF10 | c.1373C>G p.P458R | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV58045738; called by muse, mutect2, varscan2
- ROBO4 | c.1101G>T p.W367C | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60624545; called by muse, mutect2
- RYR1 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as CM123701, COSV62099142, COSV62100322; called by muse, mutect2, varscan2
- SDK1 | c.5949G>T p.E1983D | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV67371402; called by muse, mutect2, varscan2
- SERPINB8 | c.393T>A p.H131Q | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.517); catalogued as COSV54639799; called by muse, mutect2, varscan2
- SLA | c.119C>A p.P40H (on ENST00000338087 / NM_001045556.3; = p.P80H on NM_006748.4) | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV99599227, COSV99599607; called by muse, mutect2, varscan2
- SLC23A2 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100594920, COSV57775097; called by muse, mutect2, varscan2
- SLC52A3 | c.1007T>G p.L336R | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54077595; called by muse, mutect2, varscan2
- SLC5A8 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73310720; called by muse, mutect2, varscan2
- SLCO1B3 | c.820A>T p.I274L | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV53938699; called by muse, mutect2, varscan2
- SMAP2 | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV65532577; called by muse, mutect2, varscan2
- SMARCC2 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 39/214 reads (18%) | catalogued as COSV57219133; called by muse, mutect2, varscan2
- SMG6 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 70/621 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV53968164; called by muse, mutect2, varscan2
- SP4 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 19/161 reads (12%) | catalogued as COSV56023061; called by muse, mutect2, varscan2
- SPEF2 | c.4628C>T p.S1543L | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV57429547; called by muse, mutect2
- STS | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54268717; called by muse, mutect2, varscan2
- TAF1L | c.2195G>T p.G732V | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV54260577, COSV54262827; called by muse, mutect2, varscan2
- TBC1D14 | c.1626T>G p.F542L | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV68985999; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 20/95 reads (21%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- TRPM2 | c.4168G>T p.G1390C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55970460; called by muse, mutect2
- TSHZ1 | c.1106G>T p.G369V (on ENST00000580243 / NM_001308210.2; = p.G324V on NM_005786.6) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV59010529; called by muse, mutect2, varscan2
- UBTF | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 47/237 reads (20%) | catalogued as COSV57186450; called by muse, mutect2, varscan2
- ULK2 | c.2359G>T p.A787S | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.265); catalogued as COSV64446164; called by muse, mutect2, varscan2
- UPRT | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974449, COSV64912365, COSV64912563; called by muse, mutect2, varscan2
- VCAM1 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as rs769862238, COSV54119336, COSV54119728; called by muse, mutect2, varscan2
- XIAP | c.447A>G p.I149M | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63022553; called by muse, mutect2, varscan2
- ZFHX4 | c.6767T>C p.I2256T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs774800466, COSV50894559; called by mutect2, varscan2
- ZFYVE9 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.084); catalogued as rs1010354473, COSV55094548; called by muse, mutect2, varscan2
- ZMYND12 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV65342116; called by muse, mutect2, varscan2
- ZNF496 | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 103/374 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.367); catalogued as COSV54177936; called by muse, mutect2, varscan2
- ZNF532 | c.3369T>A p.D1123E | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60173435; called by muse, mutect2, varscan2
- ZNF585A | c.335G>A p.S112N (on ENST00000292841 / NM_001288800.2; = p.S57N on NM_152655.3) | Missense Mutation (SNP) | VAF 22/403 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs779348254, COSV53064208; called by muse, mutect2
- ZNF75A | c.377A>T p.H126L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV73039626; called by muse, mutect2, varscan2
- ZNF99 | c.8C>G p.S3W | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.431); catalogued as COSV68055465, COSV68055886, COSV68056062; called by muse, mutect2, varscan2
- ATP11A | c.1217del p.G406Dfs*50 | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | called by mutect2, pindel, varscan2
- CAD | c.4970del p.K1657Rfs*51 | Frame Shift Del (DEL) | VAF 54/347 reads (16%) | called by mutect2, pindel, varscan2
- CDC34 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- COL4A2 | c.3081del p.R1028Gfs*39 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, varscan2
- IGKV1D-16 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MRC1 | c.2816C>A p.P939H | Missense Mutation (SNP) | VAF 165/698 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- PIK3R6 | c.1867A>T p.S623C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- RBP3 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM248 | c.391dup p.R131Pfs*40 | Frame Shift Ins (INS) | VAF 33/213 reads (15%) | called by mutect2, pindel, varscan2
- TRAV12-3 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TRAV13-2 | c.30C>A p.Y10* | Nonsense Mutation (SNP) | VAF 36/218 reads (17%) | called by muse, mutect2, varscan2
- ABCG5 | c.1293G>T p.P431= | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as COSV53210539, COSV53211219; called by muse, mutect2, varscan2
- ADAM12 | c.1890G>A p.G630= | Silent (SNP) | VAF 90/660 reads (14%) | catalogued as COSV64107664; called by muse, mutect2, varscan2
- ARHGEF3 | c.1464A>G p.Q488= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as rs1273478770, COSV56327601; called by muse, mutect2, varscan2
- ATP11C | c.72A>T p.T24= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV59565179, COSV59575007; called by muse, mutect2, varscan2
- AXL | c.978G>T p.V326= | Silent (SNP) | VAF 33/264 reads (13%) | catalogued as COSV56569006; called by muse, mutect2, varscan2
- BRF2 | c.420G>T p.T140= | Silent (SNP) | VAF 82/731 reads (11%) | catalogued as COSV55104048, COSV99604788; called by muse, mutect2, varscan2
- CCL4 | c.21C>G p.V7= | Silent (SNP) | VAF 169/1015 reads (17%) | called by muse, mutect2, varscan2
- CLEC3A | c.219G>T p.L73= (on ENST00000651443; = p.L64= on NM_005752.6) | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV55221849; called by muse, mutect2, varscan2
- CTNNA3 | c.687T>C p.S229= | Silent (SNP) | VAF 44/224 reads (20%) | catalogued as COSV65588056; called by muse, mutect2, varscan2
- CX3CL1 | c.1131G>C p.A377= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV50055990; called by muse, mutect2, varscan2
- CYP2E1 | c.222G>T p.S74= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV53313660; called by muse, mutect2, varscan2
- DCLK1 | c.1593G>T p.L531= | Silent (SNP) | VAF 43/277 reads (16%) | catalogued as COSV99709736; called by muse, mutect2, varscan2
- EPB41L3 | c.1686G>T p.G562= | Silent (SNP) | VAF 52/262 reads (20%) | catalogued as COSV59455563; called by muse, mutect2, varscan2
- FCRL1 | c.450G>T p.G150= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as COSV63825540; called by muse, mutect2, varscan2
- GABRB3 | c.1158C>A p.G386= | Silent (SNP) | VAF 24/290 reads (8%) | catalogued as rs147235962, COSV54667019; called by muse, mutect2
- IHO1 | c.1218T>C p.N406= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as COSV56508034; called by muse, mutect2, varscan2
- INTU | c.963A>G p.S321= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV56540183; called by muse, mutect2
- MAP4K4 | c.1197T>A p.I399= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV56332231; called by muse, mutect2
- MUC4 | c.951C>T p.D317= | Silent (SNP) | VAF 56/335 reads (17%) | catalogued as rs1325909587, COSV62154241; called by muse, mutect2, varscan2
- MYH7 | c.5211C>A p.L1737= | Silent (SNP) | VAF 29/213 reads (14%) | catalogued as COSV62519876; called by muse, mutect2, varscan2
- OR10A7 | c.849T>A p.P283= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV58278702; called by muse, varscan2
- OR2G2 | c.750G>A p.V250= | Silent (SNP) | VAF 15/214 reads (7%) | catalogued as COSV60740737; called by muse, mutect2
- OR2L3 | c.423G>T p.V141= | Silent (SNP) | VAF 93/391 reads (24%) | catalogued as COSV63455320; called by muse, varscan2
- OR4B1 | c.102T>C p.L34= | Silent (SNP) | VAF 33/298 reads (11%) | catalogued as COSV58883052; called by muse, mutect2, varscan2
- OR4C13 | c.720C>A p.S240= | Silent (SNP) | VAF 57/342 reads (17%) | catalogued as rs782707423, COSV73648769; called by muse, mutect2, varscan2
- OR5B3 | c.477G>T p.G159= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as rs141530938, COSV58677399; called by muse, varscan2
- OR5L1 | c.348C>A p.A116= | Silent (SNP) | VAF 37/262 reads (14%) | catalogued as COSV100449962, COSV61732671; called by muse, mutect2, varscan2
- P2RY8 | c.822G>T p.V274= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as COSV67177470; called by muse, mutect2, varscan2
- PCDHB14 | c.966A>G p.T322= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as COSV53388836; called by muse, mutect2, varscan2
- PRSS55 | c.180G>A p.E60= | Silent (SNP) | VAF 38/335 reads (11%) | catalogued as COSV60808446; called by muse, mutect2, varscan2
- RASGRF1 | c.1953C>A p.A651= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV67250185; called by muse, mutect2, varscan2
- RHBDF1 | c.1284G>T p.A428= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV51955813, COSV51957297; called by muse, mutect2, varscan2
- RTKN2 | c.459A>T p.T153= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV59522633; called by muse, mutect2
- RTN4RL2 | c.195C>T p.L65= | Silent (SNP) | VAF 9/270 reads (3%) | catalogued as COSV58652180, COSV58652926; called by muse, mutect2
- SLC10A2 | c.99C>A p.V33= | Silent (SNP) | VAF 47/241 reads (20%) | catalogued as COSV55359494; called by muse, mutect2, varscan2
- SLCO1B3 | c.819C>A p.S273= | Silent (SNP) | VAF 31/194 reads (16%) | catalogued as COSV53938688; called by muse, varscan2
- SYT4 | c.1014C>A p.I338= | Silent (SNP) | VAF 29/212 reads (14%) | catalogued as COSV54900958; called by muse, mutect2, varscan2
- TBX4 | c.864G>A p.P288= | Silent (SNP) | VAF 26/260 reads (10%) | catalogued as rs1179957328, COSV53607740; ClinVar: likely benign; called by muse, mutect2, varscan2
- TERF1 | c.450C>T p.P150= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV52578091, COSV99400956; called by muse, mutect2, varscan2
- TJP3 | c.36C>T p.A12= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1412505648, COSV53663047; called by muse, mutect2, varscan2
- TTN | c.6042C>A p.T2014= (on ENST00000591111; = p.T1968= on NM_003319.4) | Silent (SNP) | VAF 85/374 reads (23%) | catalogued as COSV60104099; called by muse, mutect2, varscan2
- WNT2 | c.192C>T p.A64= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV55411370; called by muse, mutect2, varscan2
- ZNF182 | c.567A>G p.K189= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV59357530; called by muse, mutect2, varscan2
- ZNF282 | c.267C>A p.P89= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100021488; called by muse, mutect2, varscan2
- ZNF99 | c.2100T>C p.T700= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV68055883; called by muse, mutect2
- AC244258.1 | n.671C>A | RNA (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- AC244258.1 | n.672A>G | RNA (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822803 C>A | 5'Flank (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- BCAS3 | c.2075-4947C>A | Intron (SNP) | VAF 49/223 reads (22%) | catalogued as COSV101175499; called by muse, mutect2, varscan2
- SNORD115-20 | n.4T>A | RNA (SNP) | VAF 78/448 reads (17%) | called by muse, mutect2, varscan2
- SV2C | c.581-21115C>T | Intron (SNP) | VAF 39/438 reads (9%) | called by muse, mutect2
